Gene-level copy-number profile of tumor specimen ALCH-AE0V-TTP1-A from ALCHEMIST case ALCH-AE0V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.8 years (20,007 days).
Specimen ALCH-AE0V-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 15b14e6d-e99c-40ee-8040-c2cd68bf8c6d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE0V-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/6140c737-d5c0-49eb-8ad3-a682860dcf9e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 3,403; copy number 2: 45,401; copy number 3: 8,975; copy number 4: 1,123.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:137,204,082–137,229,640, 5 genes (within-gene range 0–1): TMEM203, NDOR1, RNF208, CYSRT1, RNF224.
- chr14:104,085,686–104,137,898, 4 genes: ASPG, MIR203A, MIR203B, AL359399.1.
- chr19:2,321,520–2,355,095, 2 genes (within-gene range 0–1): LSM7, SPPL2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,891. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
